Somatic mutation profile of tumor specimen TCGA-06-A5U0-01A (aliquot TCGA-06-A5U0-01A-11D-A33T-08) from TCGA case TCGA-06-A5U0, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 21.8 years (7,958 days).
Specimen TCGA-06-A5U0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fc253c9-b0f6-4daa-adfd-3ffcadc31663.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-A5U0-10A (Blood Derived Normal), aliquot TCGA-06-A5U0-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ab603d6-2f35-40c1-97db-6203398dfcda

The open-access MAF lists 36 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 21, Silent 7, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 72/115 reads (63%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 16/21 reads (76%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99497736; called by muse, mutect2
- AC004593.2 | c.887C>T p.T296M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56092507, COSV99765489; called by muse, mutect2, varscan2
- ALG13 | c.3294G>A p.W1098* | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as COSV99322446; called by muse, mutect2, varscan2
- CCDC22 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as rs1557114789, COSV100873196; called by muse, mutect2, varscan2
- COL5A3 | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 87/166 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs768794982, COSV99319239, COSV99320026; called by muse, mutect2, varscan2
- CPN2 | c.1303G>A p.V435M | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV100103165; called by muse, mutect2, varscan2
- DEPDC4 | c.745C>G p.H249D | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767452547, COSV100147379, COSV100147388; called by muse, mutect2, varscan2
- DNAH11 | c.12236G>C p.S4079T | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV100179730; called by muse, mutect2, varscan2
- FAF1 | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100875830; called by muse, mutect2, varscan2
- FBXL17 | c.1958G>A p.C653Y | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100671946; called by muse, mutect2, varscan2
- FUS | c.698A>G p.N233S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99568796; called by muse, mutect2, varscan2
- ITIH1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs763101480, COSV99835290; called by muse, mutect2, varscan2
- MCM5 | c.426G>A p.S142= | Splice Region (SNP) | VAF 17/31 reads (55%) | catalogued as rs749822398, COSV99331816; called by muse, mutect2, varscan2
- PLXNA1 | c.4157G>A p.R1386H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1559964225, COSV99303544; called by muse, mutect2, varscan2
- RAI2 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1186348212, COSV100518318; called by muse, mutect2, varscan2
- SAMD8 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as COSV65510113; called by muse, mutect2
- SLC39A10 | c.183dup p.Y62Ifs*4 | Frame Shift Ins (INS) | VAF 10/29 reads (34%) | catalogued as rs771462597; called by mutect2, varscan2
- SLC7A9 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.235); catalogued as rs375205018; called by muse, mutect2
- ST6GAL1 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 41/82 reads (50%) | PolyPhen benign (0.03); catalogued as COSV99399241; called by muse, mutect2, varscan2
- TG | c.2900A>G p.N967S | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99601834; called by muse, mutect2, varscan2
- TUBB4A | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as COSV99900055; called by muse, mutect2
- ULK1 | c.1969C>T p.R657* | Nonsense Mutation (SNP) | VAF 24/74 reads (32%) | catalogued as rs373878374, COSV58855019; called by muse, mutect2, varscan2
- ZNF93 | c.342A>G p.I114M | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV100652339; called by muse, mutect2, varscan2
- ATRX | c.6338_6341del p.F2113Sfs*9 | Frame Shift Del (DEL) | VAF 24/46 reads (52%) | called by pindel, varscan2
- FBXW7 | c.840_856del p.F280Lfs*31 (on ENST00000281708 / NM_001349798.2; = p.F200Lfs*31 on NM_018315.5) | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- TP53 | c.510_511dup p.E171Gfs*4 | Frame Shift Ins (INS) | VAF 24/74 reads (32%) | called by mutect2, pindel, varscan2
- DAZAP2 | c.108C>T p.T36= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs750548316, COSV101199410; called by muse, mutect2, varscan2
- EXOC4 | c.996G>A p.E332= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99554625; called by muse, mutect2, varscan2
- MAPK3 | c.606G>A p.T202= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs778624436, COSV99531743; called by muse, mutect2, varscan2
- SEZ6L | c.1389C>T p.R463= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs767074283, COSV50660273; called by muse, mutect2, varscan2
- SOX4 | c.177C>T p.I59= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99782087; called by muse, mutect2, varscan2
- TENT5B | c.897C>T p.R299= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as rs1167722051, COSV56692663; called by muse, mutect2, varscan2
- ZSCAN5A | c.393C>T p.V131= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV99570372; called by muse, mutect2
